Gene-level copy-number profile of tumor specimen TCGA-D3-A51T-06A from TCGA case TCGA-D3-A51T, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 59.8 years (21,857 days).
Specimen TCGA-D3-A51T-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.cedf14dd-b34a-400e-a667-3ed3954b22ef.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A51T-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/50a4f916-53ab-49d8-a350-3734fbc27a44

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,651; copy number 2: 43,284; copy number 3: 3,197; copy number 4: 1,596; copy number 5: 83.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A51T-06A-11D-A25P-01): tumor purity 0.83, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 83 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:65,309,855–67,379,994, 16 genes, copy number 5: STARP1, HNRNPA3P5, LINC01052, AL158038.1, MIR548X2, MIR4704, TRIM60P19, PCDH9, PCDH9-AS1, RNU7-87P, PCDH9-AS2, PCDH9-AS3, PCDH9-AS4, AL160254.1, RPSAP53, LINC00364.
- chr13:80,335,976–81,017,737, 6 genes, copy number 5 (within-gene range 4–5): SPRY2, RNU6-61P, HNRNPA1P31, PWWP2AP1, AL590807.1, ARF4P4.
- chr13:102,263,046–102,904,000, 20 genes, copy number 5: RPL39P29, FGF14-IT1, AL356266.1, FGF14-AS1, FGF14-AS2, LINC00555, AL158063.1, TPP2, METTL21C, CCDC168, LINC00283, AL157769.1, TEX30, POGLUT2, BIVM-ERCC5, BIVM, ERCC5, METTL21EP, AL137246.1, AL137246.2.
- chr13:104,814,327–108,481,817, 41 genes, copy number 5: RPL7P45, AL138954.1, DAOA-AS1, AL359751.2, AL359751.1, DAOA, AL359745.1, LINC00343, AL138701.1, AL138701.2, RNA5SP38, AL139379.1, LINC00460, RPL35P9, EFNB2, AL138689.2, AL138689.1, ARGLU1, LINC00551, LINC00443, ATP5MC1P5, AL163534.1, AL162574.2, PPIAP24, AL162574.1, AL162574.3, AL354741.1, FAM155A, SNORD31B, AL445649.1, MIR1267, FAM155A-IT1, AL359436.1, AL136964.1, LIG4, ABHD13, TNFSF13B, AL157762.1, RNA5SP39, AL138694.1, HCFC2P1.

Autosomal genes at a single copy (total copy number 1): 11,651. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
